PECGS case C083-000067 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/5f2aeaae-c2af-45e6-9847-92ee4650a5c8

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 47 years; Year of birth: 1973; Education level: Some High School or Less.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Age at diagnosis: 47.2 years (17,240 days); AJCC clinical stage: Stage IIIB; AJCC pathologic stage: Stage IIIA; Progression or recurrence: no.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample C083-000067_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000067_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
